Somatic mutation profile of tumor specimen BLGSP-71-08-00039-01A (aliquot BLGSP-71-08-00039-01A-01D-A663-33) from CGCI case BLGSP-71-08-00039, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.0 years (2,563 days).
Specimen BLGSP-71-08-00039-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c41250e-842c-4068-98fc-8faeb6550dda.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-08-00039-10A (Blood Derived Normal), aliquot BLGSP-71-08-00039-10A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f1ee206-6d1f-4945-908b-42d00205cc53

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 3, Missense Mutation 3, Intron 3, In Frame Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1331T>C p.L444S (on ENST00000399959; = p.L445S on NM_001356.5) | Missense Mutation (SNP) | VAF 271/588 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101302553; called by muse, mutect2, varscan2
- H2BC12 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); catalogued as COSV104418606; called by muse, mutect2, varscan2
- ARID1A | c.3164_3165del p.Y1055Cfs*49 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- DDX3X | c.119_121del p.P40del (on ENST00000399959; = p.P41del on NM_001356.5) | In Frame Del (DEL) | VAF 16/128 reads (13%) | called by pindel, varscan2
- FBXO11 | c.2533T>G p.Y845D (on ENST00000403359 / NM_001190274.2; = p.Y761D on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RHOA | c.355_357del p.K119del | In Frame Del (DEL) | VAF 108/252 reads (43%) | called by pindel, varscan2
- SIN3A | c.1519_1523del p.F507Gfs*5 | Frame Shift Del (DEL) | VAF 97/274 reads (35%) | called by mutect2, pindel, varscan2
- TFAP4 | c.61_64del p.E21Kfs*3 | Frame Shift Del (DEL) | VAF 53/113 reads (47%) | called by mutect2, pindel, varscan2
- BCL7A | chr12:122021495 G>A | 5'Flank (SNP) | VAF 49/118 reads (42%) | catalogued as rs966798991; called by muse, mutect2, varscan2
- CASC11 | n.143+3131T>G | Intron (SNP) | VAF 158/303 reads (52%) | called by muse, mutect2, varscan2
- DDX3X | c.104-10T>A | Intron (SNP) | VAF 18/64 reads (28%) | called by muse, varscan2
- TMSB4X | c.-17+202C>G | Intron (SNP) | VAF 131/281 reads (47%) | catalogued as COSV66081094; called by muse, mutect2, varscan2
